Somatic mutation profile of tumor specimen C3L-03395-02 (aliquot CPT0276010006) from CPTAC case C3L-03395, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 78.0 years (28,498 days).
Specimen C3L-03395-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be370138-51a5-4853-a731-242b6834e18c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03395-31 (Blood Derived Normal), aliquot CPT0265950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ba69982-1a62-48c4-88ad-6ef439fa0269

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, 5'UTR 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/432 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 29/554 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2
- CLCN1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 25/503 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs756490905; called by muse, mutect2
- COL5A1 | c.4748C>T p.T1583M | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as rs375076580; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- DNAH17 | c.9517G>A p.A3173T | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs759137847, COSV67757976; called by muse, mutect2
- HSPA12A | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs199760082; called by muse, mutect2
- MAP1B | c.2398G>A p.G800S | Missense Mutation (SNP) | VAF 28/441 reads (6%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as rs778950672, COSV99702156; called by muse, mutect2
- MXRA5 | c.8237G>A p.R2746Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750982915; called by muse, mutect2
- OBSCN | c.11872G>A p.E3958K | Missense Mutation (SNP) | VAF 41/1023 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs746344428, COSV52751636; called by muse, mutect2
- PLCB3 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1301364795, COSV99657301; called by muse, mutect2
- PLK5 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 37/491 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs774146463; called by muse, mutect2
- SYT5 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 12/395 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV62830395; called by muse, mutect2
- WNT5B | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs112329239, COSV100148791; called by muse, mutect2
- ATP11B | c.1772T>A p.L591* | Nonsense Mutation (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- DHX38 | c.819A>C p.K273N | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.849); called by muse, mutect2
- H1-4 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV3-72 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 21/519 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- SPTBN4 | c.6715C>T p.R2239C | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- TRIP13 | c.1118T>C p.L373S | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- UQCRC2 | c.680A>T p.H227L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF582 | c.741A>C p.R247S | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF879 | c.708A>T p.E236D | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2
- BTBD17 | c.253C>T p.L85= | Silent (SNP) | VAF 37/692 reads (5%) | catalogued as rs1227034998; called by muse, mutect2
- CALHM3 | c.714C>T p.F238= | Silent (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- HOXA9 | c.366G>A p.A122= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1275743750, COSV100604363; called by muse, mutect2
- MUC20 | c.1644A>T p.G548= | Silent (SNP) | VAF 20/482 reads (4%) | called by muse, mutect2
- SOD3 | c.126C>A p.V42= | Silent (SNP) | VAF 48/838 reads (6%) | called by muse, mutect2
- ZNF135 | c.1776G>T p.S592= (on ENST00000313434 / NM_001289401.2; = p.S604= on NM_003436.4) | Silent (SNP) | VAF 36/391 reads (9%) | catalogued as rs367729073, COSV57883142; called by muse, mutect2
- ARHGEF4 | c.-271G>A | 5'UTR (SNP) | VAF 18/239 reads (8%) | called by muse, mutect2
- COL6A2 | c.2462-2603G>A | Intron (SNP) | VAF 15/477 reads (3%) | catalogued as rs1452657940; called by muse, mutect2
- SOHLH1 | c.-28C>T | 5'UTR (SNP) | VAF 28/462 reads (6%) | catalogued as rs369133496, COSV100039967; called by muse, mutect2
